Somatic mutation profile of tumor specimen 0DR9C7 from CCDI case PBCGEL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ganglioglioma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 18.5 years (6,771 days).
Specimen 0DR9C7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2c227b44-5c91-40c5-90b3-a8dbb8fc62ae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DR9CV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/654ff4b3-bb35-464e-bc70-abe383aaa374

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 163/1847 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2
- C10orf105 | c.79G>A p.G27R | Missense Mutation (SNP) | VAF 51/1366 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.209); catalogued as rs1439998328, COSV99823829; called by muse, mutect2
- RBM12 | c.173T>A p.M58K | Missense Mutation (SNP) | VAF 74/1589 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.783); called by muse, mutect2
- TMF1 | c.2522A>G p.E841G | Missense Mutation (SNP) | VAF 62/1858 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 46/467 reads (10%) | called by muse, varscan2
